Somatic mutation profile of tumor specimen TCGA-60-2723-01A (aliquot TCGA-60-2723-01A-01W-0877-08) from TCGA case TCGA-60-2723, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.5 years (27,225 days).
Specimen TCGA-60-2723-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d59edb1-2349-4e10-af39-4fd652bd958a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2723-11A (Solid Tissue Normal), aliquot TCGA-60-2723-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdc47439-ce2a-4d38-98a7-d40b7e28c258

The open-access MAF lists 286 somatic variants for this specimen: 229 protein-altering or splice-affecting, 55 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 193, Silent 55, Nonsense Mutation 11, Frame Shift Del 10, Splice Region 4, Splice Site 4, Frame Shift Ins 3, Intron 2, In Frame Del 2, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.4229C>A p.S1410Y | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.937); catalogued as COSV70043399; called by muse, mutect2, varscan2
- ABCD2 | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.101); catalogued as COSV58055017; called by muse, mutect2, varscan2
- AC004593.2 | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 318/577 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as rs934664832, COSV56095903; called by muse, varscan2
- ACSM1 | c.523A>G p.I175V | Missense Mutation (SNP) | VAF 77/240 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54639929; called by muse, mutect2, varscan2
- ACTL6B | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50518325; called by muse, mutect2, varscan2
- ADAMTS12 | c.4451C>A p.S1484Y | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV61278656; called by muse, mutect2, varscan2
- ADAMTS20 | c.2365G>A p.V789M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV67138751; called by muse, mutect2, varscan2
- ADCY8 | c.3025C>T p.R1009C | Missense Mutation (SNP) | VAF 349/1206 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1475267602, COSV53905124; called by muse, mutect2, varscan2
- ADCY8 | c.2879C>T p.A960V | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53926260; called by muse, mutect2, varscan2
- ADGRG7 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56299253; called by muse, mutect2, varscan2
- AFF1 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 171/469 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs561558992, COSV57117810; called by muse, mutect2, varscan2
- AGAP2 | c.1683G>C p.E561D (on ENST00000547588 / NM_001122772.2; = p.E225D on NM_014770.4) | Missense Mutation (SNP) | VAF 150/325 reads (46%) | SIFT tolerated (0.9); PolyPhen benign (0.018); catalogued as COSV57728167, COSV57730210, COSV57731479; called by muse, mutect2, varscan2
- AGBL1 | c.2405G>T p.R802L | Missense Mutation (SNP) | VAF 5/119 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66869099; called by muse, mutect2
- ANAPC1 | c.4537G>T p.E1513* | Nonsense Mutation (SNP) | VAF 36/156 reads (23%) | catalogued as COSV61979368; called by muse, mutect2, varscan2
- APOBEC1 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57550175, COSV99981018; called by muse, mutect2, varscan2
- APOBEC3D | c.793A>G p.R265G | Missense Mutation (SNP) | VAF 180/609 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs1400558719, COSV53328645; called by muse, varscan2
- ATP7A | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV58453549; called by muse, mutect2, varscan2
- BCHE | c.1219G>T p.D407Y | Missense Mutation (SNP) | VAF 63/270 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV52262192; called by muse, mutect2, varscan2
- BIRC6 | c.4047G>C p.Q1349H | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV70205518; called by muse, mutect2, varscan2
- BPIFB4 | c.1054C>A p.L352M | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV64952303; called by muse, mutect2, varscan2
- CACNA1E | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 193/800 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62392498, COSV62416591; called by muse, mutect2, varscan2
- CACNA1S | c.2594G>A p.R865H | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs545411173, COSV62943438; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- CACNA2D4 | c.1619T>A p.L540Q | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54959609; called by muse, mutect2, varscan2
- CACNB3 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV56400839; called by muse, mutect2, varscan2
- CADPS2 | c.2756G>T p.C919F | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as COSV57384765; called by muse, mutect2, varscan2
- CALHM4 | c.750G>T p.K250N (on ENST00000368596 / NM_001366078.1; = p.K64N on NM_153036.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.25); catalogued as COSV63985748, COSV63985933; called by muse, mutect2, varscan2
- CCDC150 | c.1909A>T p.T637S | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.085); catalogued as COSV55878375; called by muse, varscan2
- CCDC27 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV53901618; called by muse, mutect2, varscan2
- CCM2L | c.1170C>G p.S390R (on ENST00000452892 / NM_001365692.1; = p.A369G on NM_080625.4) | Missense Mutation (SNP) | VAF 44/235 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV52952552; called by muse, mutect2, varscan2
- CCN4 | c.444C>A p.D148E | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.28); catalogued as COSV51532431, COSV51535531; called by muse, mutect2, varscan2
- CD209 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 102/316 reads (32%) | catalogued as COSV52658533; called by muse, mutect2, varscan2
- CD300LF | c.671T>A p.L224H | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.339); catalogued as COSV56899056; called by muse, mutect2, varscan2
- CD96 | c.715T>C p.F239L (on ENST00000283285 / NM_198196.3; = p.F223L on NM_005816.5) | Missense Mutation (SNP) | VAF 117/486 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV51922661; called by muse, mutect2, varscan2
- CDH18 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776963132, COSV56899350; called by muse, mutect2
- CDH2 | c.602G>C p.G201A | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52295468, COSV52295962; called by muse, mutect2, varscan2
- CDK15 | c.886G>T p.G296C (on ENST00000652192 / NM_001366386.2; = p.G245C on NM_139158.2) | Missense Mutation (SNP) | VAF 50/290 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53638345, COSV99643813; called by muse, mutect2, varscan2
- CECR2 | c.2200A>G p.I734V (on ENST00000342247 / NM_001290047.2; = p.I551V on NM_001290046.1) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV52847780; called by muse, mutect2, varscan2
- CLTCL1 | c.3063C>T p.H1021= | Splice Region (SNP) | VAF 22/55 reads (40%) | catalogued as rs1041665106, COSV54238700; called by muse, mutect2, varscan2
- CLVS2 | c.537G>C p.M179I | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51568777; called by muse, mutect2, varscan2
- CNTNAP2 | c.2375A>G p.Q792R | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1445975540, COSV62252473; called by muse, mutect2, varscan2
- CNTNAP4 | c.3508G>A p.A1170T | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.559); catalogued as COSV56699258; called by muse, mutect2, varscan2
- COL11A1 | c.1245C>A p.S415R | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.339); catalogued as rs371490794, COSV62185051, COSV62196610; called by muse, mutect2, varscan2
- COL12A1 | c.8098G>T p.A2700S | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV59392888, COSV59407435; called by muse, mutect2, varscan2
- COL1A2 | c.1945G>A p.G649S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV51957004, COSV51965780; called by muse, mutect2, varscan2
- COL22A1 | c.640C>G p.R214G | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57331225, COSV57359419; called by muse, mutect2, varscan2
- CSMD2 | c.8847C>A p.V2949= | Splice Region (SNP) | VAF 64/166 reads (39%) | catalogued as COSV53959619; called by muse, mutect2, varscan2
- CYBB | c.865del p.W289Gfs*24 | Frame Shift Del (DEL) | VAF 101/810 reads (12%) | catalogued as COSV66085572; called by mutect2, pindel, varscan2
- CYLC2 | c.843C>G p.D281E | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs201302612, COSV66336518, COSV66339368; called by muse, mutect2, varscan2
- DCC | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.899); catalogued as COSV71440297; called by muse, mutect2, varscan2
- DCDC2 | c.1284C>A p.D428E | Missense Mutation (SNP) | VAF 114/782 reads (15%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as COSV65829820; called by muse, mutect2, varscan2
- DEPDC1B | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV99409761; called by muse, varscan2
- DEPDC1B | c.369G>T p.K123N | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99409763; called by muse, varscan2
- DGKK | c.2447G>T p.R816L | Missense Mutation (SNP) | VAF 133/401 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV65708298, COSV65709338; called by muse, mutect2, varscan2
- DLG2 | c.1398G>T p.Q466H | Missense Mutation (SNP) | VAF 69/269 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV54683185, COSV54685776; called by muse, mutect2, varscan2
- DNAH10 | c.6478A>T p.M2160L (on ENST00000409039; = p.M2099L on NM_207437.3) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV69001075; called by muse, mutect2, varscan2
- DNAH3 | c.3498G>T p.K1166N | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV54549809, COSV54550066; called by muse, mutect2, varscan2
- DNAH8 | c.3496G>T p.D1166Y | Missense Mutation (SNP) | VAF 80/214 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.686); catalogued as COSV59478767; called by muse, mutect2, varscan2
- DNAH9 | c.12006C>G p.I4002M | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV52375639; called by muse, varscan2
- DNAJC13 | c.250A>G p.K84E | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV53457826; called by muse, mutect2
- DNAJC21 | c.1310A>G p.E437G | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100331519; called by muse, mutect2, varscan2
- DPF3 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | catalogued as COSV63503048; called by muse, mutect2, varscan2
- DZIP3 | c.2886G>T p.M962I | Missense Mutation (SNP) | VAF 118/359 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1330184909, COSV64313776; called by muse, mutect2, varscan2
- EML2 | c.834G>A p.W278* | Nonsense Mutation (SNP) | VAF 10/106 reads (9%) | catalogued as COSV55603722; called by muse, mutect2
- ERBB2 | c.900C>T p.P300= | Splice Region (SNP) | VAF 8/21 reads (38%) | catalogued as COSV54082449; called by muse, mutect2, varscan2
- ERICH3 | c.3559G>T p.D1187Y | Missense Mutation (SNP) | VAF 259/883 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV58617774; called by muse, mutect2, varscan2
- F8 | c.3098A>T p.H1033L | Missense Mutation (SNP) | VAF 124/325 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV64278386; called by muse, mutect2, varscan2
- FABP5 | c.314G>T p.S105I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs757111208, COSV51917918; called by muse, mutect2, varscan2
- FAM135B | c.2458G>A p.G820R | Missense Mutation (SNP) | VAF 115/325 reads (35%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV52752187; called by muse, mutect2, varscan2
- FAM135B | c.719G>T p.W240L | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV52749876; called by muse, mutect2, varscan2
- FCRL2 | c.404A>G p.Q135R | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.151); catalogued as COSV63835042; called by muse, mutect2, varscan2
- FCRL3 | c.1013C>A p.S338Y | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV63844802; called by muse, mutect2, varscan2
- FGD5 | c.1474T>G p.Y492D | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.404); catalogued as COSV53251658; called by muse, mutect2, varscan2
- FGF2 | c.645C>A p.Y215* | Nonsense Mutation (SNP) | VAF 80/222 reads (36%) | catalogued as COSV52651315, COSV52652869; called by muse, mutect2, varscan2
- FOXD1 | c.494A>G p.K165R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs746178308, COSV61076826; called by muse, mutect2
- FRZB | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV54556005; called by muse, mutect2, varscan2
- FYB1 | c.1394T>A p.I465K | Missense Mutation (SNP) | VAF 49/236 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60955999; called by muse, mutect2, varscan2
- GALNT5 | c.383A>T p.H128L | Missense Mutation (SNP) | VAF 65/382 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV52041092; called by muse, mutect2, varscan2
- GIMAP2 | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV56236295; called by muse, mutect2, varscan2
- GOLGA1 | c.1477A>G p.R493G | Missense Mutation (SNP) | VAF 114/293 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs774962630, COSV63024251; called by muse, mutect2, varscan2
- GRM5 | c.1321del p.L441* | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | catalogued as COSV100549843; called by mutect2, pindel, varscan2
- H2AC17 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.119); catalogued as rs372303389, COSV58153994; called by muse, mutect2, varscan2
- HAND2 | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64019064; called by muse, mutect2, varscan2
- HCK | c.1445G>T p.C482F | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52946984; called by muse, mutect2, varscan2
- HEG1 | c.3865G>T p.D1289Y | Missense Mutation (SNP) | VAF 53/265 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769086150, COSV60765413; called by muse, mutect2, varscan2
- HGF | c.616T>C p.C206R | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55956463; called by muse, mutect2, varscan2
- HK3 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV52844295; called by muse, mutect2, varscan2
- IGKV1-8 | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 87/300 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs1253171805; called by muse, mutect2, varscan2
- IL17F | c.23G>A p.G8D | Missense Mutation (SNP) | VAF 90/232 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60235218; called by muse, mutect2, varscan2
- IL18RAP | c.1445G>A p.S482N | Missense Mutation (SNP) | VAF 96/369 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51829181; called by muse, mutect2, varscan2
- IL2RB | c.136T>G p.C46G | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53428461; called by muse, mutect2, varscan2
- IZUMO1R | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 227/1519 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.801); catalogued as COSV60623506; called by muse, mutect2, varscan2
- JAG1 | c.3048T>A p.I1016= | Splice Region (SNP) | VAF 55/178 reads (31%) | catalogued as COSV54762518; called by muse, mutect2, varscan2
- JAK2 | c.2968G>C p.V990L | Missense Mutation (SNP) | VAF 636/812 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67671801; called by muse, mutect2, varscan2
- KCNK17 | c.503dup p.T169Hfs*6 | Frame Shift Ins (INS) | VAF 27/96 reads (28%) | catalogued as rs1289056210; called by pindel, varscan2
- KEAP1 | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as COSV50501375, COSV50643386; called by muse, mutect2, varscan2
- KIR3DL1 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 154/392 reads (39%) | catalogued as COSV58495866; called by muse, mutect2, varscan2
- KIRREL2 | c.931G>T p.G311W | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV52879953; called by muse, mutect2, varscan2
- LARP7 | c.1668+1G>T p.X556_splice | Splice Site (SNP) | VAF 18/63 reads (29%) | catalogued as COSV60522241; called by muse, mutect2, varscan2
- LDHAL6A | c.680G>C p.W227S | Missense Mutation (SNP) | VAF 87/195 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52652779; called by muse, mutect2, varscan2
- LRFN5 | c.1551C>A p.C517* | Nonsense Mutation (SNP) | VAF 90/452 reads (20%) | catalogued as COSV53250921, COSV53274100; called by muse, mutect2, varscan2
- LRFN5 | c.1552C>T p.H518Y | Missense Mutation (SNP) | VAF 89/450 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs765807336, COSV53274108; called by muse, mutect2, varscan2
- LRRC37A2 | c.3689C>A p.A1230D | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV61004380; called by muse, mutect2, varscan2
- MAGI2 | c.982A>G p.T328A | Missense Mutation (SNP) | VAF 133/419 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62697070; called by muse, mutect2, varscan2
- MARCO | c.205A>C p.N69H | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV59058416; called by muse, mutect2, varscan2
- MCM5 | c.385A>C p.K129Q | Missense Mutation (SNP) | VAF 100/222 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV53348153; called by muse, mutect2, varscan2
- MED1 | c.4342C>G p.P1448A | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100327879, COSV56128385; called by muse, varscan2
- METTL6 | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV67542605; called by muse, mutect2, varscan2
- MROH2B | c.2287G>T p.G763C | Missense Mutation (SNP) | VAF 104/553 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV68189258; called by muse, mutect2, varscan2
- MUC17 | c.398C>G p.T133S | Missense Mutation (SNP) | VAF 55/261 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV60302591; called by muse, mutect2, varscan2
- MUC17 | c.7809A>G p.I2603M | Missense Mutation (SNP) | VAF 65/417 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV60302599; called by muse, mutect2, varscan2
- MUC3A | c.7327C>A p.L2443I | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious, low confidence (0.02); catalogued as rs73163756; called by muse, mutect2, varscan2
- MUC3A | c.7328T>A p.L2443H | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious, low confidence (0); catalogued as rs750472138, COSV60224328; called by muse, mutect2, varscan2
- MYH1 | c.4269G>C p.Q1423H | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.285); catalogued as COSV56856779; called by muse, mutect2, varscan2
- MYH13 | c.5107C>A p.R1703S | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52842071, COSV52842304; called by muse, mutect2, varscan2
- MYH13 | c.3502A>G p.N1168D | Missense Mutation (SNP) | VAF 171/489 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs759892824, COSV52842088; called by muse, mutect2, varscan2
- MYH4 | c.4661C>T p.S1554F | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV55125773; called by muse, mutect2, varscan2
- MYPN | c.2189C>A p.T730K | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV62738993; called by muse, mutect2, varscan2
- NAALAD2 | c.1447C>A p.L483M | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as COSV58965905; called by muse, mutect2, varscan2
- NAV3 | c.5318C>G p.P1773R | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.422); catalogued as rs1367201584, COSV57110792, COSV99894160; called by muse, mutect2, varscan2
- NCAPG2 | c.2231A>T p.K744I | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV51991553; called by muse, mutect2, varscan2
- NEMF | c.2388G>T p.L796F | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV53595146; called by muse, mutect2
- NPHP4 | c.4168G>T p.G1390C | Missense Mutation (SNP) | VAF 93/284 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65397685; called by muse, mutect2, varscan2
- NRAP | c.4886C>T p.P1629L (on ENST00000359988 / NM_001322945.2; = p.P1594L on NM_006175.4) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV63493784; called by muse, mutect2, varscan2
- NRCAM | c.3764T>C p.L1255P (on ENST00000379028 / NM_001371124.1; = p.L1134P on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 195/620 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61048431; called by muse, mutect2, varscan2
- NRP2 | c.1917G>T p.Q639H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55935239; called by muse, mutect2, varscan2
- OBSCN | c.8912G>C p.R2971P | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV52825882; called by muse, mutect2, varscan2
- OR10G9 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 100/643 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV66686805; called by muse, mutect2, varscan2
- OR2AK2 | c.800C>G p.S267C | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV63560536; called by muse, mutect2, varscan2
- OR2B3 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.382); catalogued as COSV65851176; called by muse, mutect2, varscan2
- OR2M2 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 356/1326 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV62899371; called by muse, mutect2, varscan2
- OR4C12 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 41/131 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as COSV58861052, COSV58861220; called by muse, mutect2, varscan2
- OR4C6 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 120/382 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.102); catalogued as rs756494196, COSV58606184; called by muse, mutect2, varscan2
- OR4S2 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 214/653 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56748333; called by muse, varscan2
- OR4S2 | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 146/388 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV56748343; called by muse, mutect2, varscan2
- OR51B4 | c.789A>T p.K263N | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.33); catalogued as COSV66517750; called by muse, mutect2, varscan2
- OR5L2 | c.299A>G p.Q100R | Missense Mutation (SNP) | VAF 212/501 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65725081; called by muse, mutect2, varscan2
- OR8J3 | c.755A>T p.Y252F | Missense Mutation (SNP) | VAF 90/173 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56884159; called by muse, mutect2, varscan2
- OR9I1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 36/358 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV56927470; called by muse, mutect2, varscan2
- PAN3 | c.1721G>C p.G574A | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.971); catalogued as COSV56707334; called by muse, mutect2, varscan2
- PAPPA | c.1570G>C p.E524Q | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV60277604, COSV60291325; called by muse, mutect2, varscan2
- PCDHB3 | c.2192C>A p.P731H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.018); catalogued as COSV50605047; called by muse, mutect2, varscan2
- PCDHGA4 | c.2083G>T p.V695L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.316); catalogued as COSV54027165; called by muse, mutect2, varscan2
- PDP1 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); catalogued as rs1429816363, COSV52603788; called by muse, mutect2, varscan2
- PIK3R2 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55850240; called by muse, mutect2, varscan2
- PKHD1L1 | c.3388C>G p.P1130A | Missense Mutation (SNP) | VAF 92/316 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV65752371; called by muse, mutect2, varscan2
- PKNOX2 | c.1262T>C p.M421T | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV53554240; called by muse, mutect2, varscan2
- PLA2G6 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.442); catalogued as COSV59273390; called by muse, mutect2, varscan2
- PLPPR4 | c.2224A>T p.N742Y | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.36); catalogued as COSV64567633; called by muse, mutect2, varscan2
- PRAME | c.1432A>T p.S478C | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV67162456; called by muse, mutect2, varscan2
- PREX1 | c.3188G>T p.G1063V | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64255951, COSV64256589; called by muse, mutect2, varscan2
- PRKCG | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV54732606; called by muse, mutect2, varscan2
- PRKCG | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV54732618; called by muse, mutect2, varscan2
- PRLR | c.683G>C p.S228T | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV51497109, COSV51500405; called by muse, mutect2, varscan2
- PROM1 | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.18); catalogued as rs371004406, COSV71699978; called by muse, mutect2, varscan2
- PUM2 | c.1104C>A p.N368K | Missense Mutation (SNP) | VAF 54/464 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.127); catalogued as COSV57585190; called by muse, mutect2, varscan2
- RALGAPA2 | c.4656G>C p.M1552I | Missense Mutation (SNP) | VAF 101/367 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.05); catalogued as COSV52510442; called by muse, mutect2, varscan2
- RALGPS2 | c.1748A>G p.E583G | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62685347; called by muse, mutect2, varscan2
- RCN2 | c.488A>G p.Q163R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV58031973; called by muse, mutect2, varscan2
- RFLNB | c.268C>G p.P90A | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.063); catalogued as COSV61239949; called by muse, mutect2
- RFLNB | c.267G>T p.R89S | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV61239957; called by muse, mutect2
- RNF148 | c.860C>G p.P287R | Missense Mutation (SNP) | VAF 90/366 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57360909; called by muse, mutect2, varscan2
- SAMD14 | c.838G>A p.D280N (on ENST00000330175 / NM_001257359.2; = p.D308N on NM_174920.4) | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.227); catalogued as COSV50304992; called by muse, mutect2, varscan2
- SAMD9 | c.4125A>T p.Q1375H | Missense Mutation (SNP) | VAF 41/304 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV66077415; called by muse, mutect2, varscan2
- SARDH | c.1102G>C p.V368L | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as rs1198632722, COSV64097708; called by muse, mutect2, varscan2
- SCN2A | c.5878C>G p.P1960A | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as COSV51854527; called by muse, mutect2, varscan2
- SDR16C5 | c.694del p.E232Kfs*23 | Frame Shift Del (DEL) | VAF 30/114 reads (26%) | catalogued as COSV100374090, COSV58125587; called by mutect2, pindel, varscan2
- SEL1L2 | c.678G>T p.L226F | Missense Mutation (SNP) | VAF 40/267 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.767); catalogued as rs1325897740, COSV53157974; called by muse, mutect2, varscan2
- SEMA6C | c.762G>T p.Q254H | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59007613; called by muse, mutect2, varscan2
- SERPING1 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV53544250; called by muse, mutect2, varscan2
- SETD2 | c.6046T>C p.W2016R | Missense Mutation (SNP) | VAF 238/590 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57451226; called by muse, mutect2, varscan2
- SETX | c.7484T>C p.L2495P | Missense Mutation (SNP) | VAF 103/230 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV56394210; called by muse, mutect2, varscan2
- SLC6A12 | c.410T>A p.L137H | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62886133; called by muse, mutect2, varscan2
- SLC9B2 | c.996+1G>T p.X332_splice | Splice Site (SNP) | VAF 120/340 reads (35%) | catalogued as rs1242801717, COSV60022150; called by muse, mutect2, varscan2
- SNTG2 | c.412G>T p.V138L | Missense Mutation (SNP) | VAF 95/432 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs777135474, COSV58005400; called by muse, mutect2, varscan2
- SORCS1 | c.1781G>C p.G594A | Missense Mutation (SNP) | VAF 102/238 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53903462; called by muse, mutect2, varscan2
- SPEG | c.9069G>C p.M3023I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV56679250; called by mutect2, varscan2
- SPINT4 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as COSV54142724, COSV54143294; called by muse, mutect2, varscan2
- SPRED1 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 65/175 reads (37%) | catalogued as COSV104406857, COSV54438998; called by muse, mutect2, varscan2
- SULT1C2 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 151/591 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs547819243, COSV52267067; called by muse, mutect2, varscan2
- SYCP2 | c.322A>G p.K108E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV62772363; called by muse, mutect2, varscan2
- SYT6 | c.1440C>A p.N480K (on ENST00000610222 / NM_001366225.1; = p.N395K on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.915); catalogued as COSV101059600, COSV65773774; called by muse, mutect2, varscan2
- TAF1L | c.3869G>T p.G1290V | Missense Mutation (SNP) | VAF 121/362 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54268755; called by muse, mutect2, varscan2
- TAF1L | c.3868G>T p.G1290* | Nonsense Mutation (SNP) | VAF 120/357 reads (34%) | catalogued as COSV54261123, COSV54268768; called by muse, mutect2, varscan2
- TEP1 | c.7630C>T p.H2544Y | Missense Mutation (SNP) | VAF 91/227 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs372031810; called by muse, mutect2, varscan2
- THY1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 46/321 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52455232; called by muse, mutect2, varscan2
- TLE6 | c.770C>T p.A257V (on ENST00000246112 / NM_001143986.2; = p.A134V on NM_024760.3) | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs1233031120, COSV55737715; called by muse, mutect2, varscan2
- TMEM108 | c.247A>G p.T83A | Missense Mutation (SNP) | VAF 77/430 reads (18%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.06); catalogued as COSV58882517; called by muse, mutect2, varscan2
- TMEM248 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV58577824; called by muse, mutect2, varscan2
- TMPRSS7 | c.2097G>T p.Q699H (on ENST00000452346; = p.Q573H on NM_001042575.2) | Missense Mutation (SNP) | VAF 131/722 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69982511; called by muse, mutect2, varscan2
- TNNI3K | c.2281G>T p.A761S | Missense Mutation (SNP) | VAF 176/968 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.985); catalogued as COSV53952223, COSV53953568; called by muse, mutect2, varscan2
- TONSL | c.3722G>T p.R1241L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV52871180, COSV52873463; called by muse, mutect2, varscan2
- TOP1 | c.158A>G p.E53G | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV63696011; called by muse, mutect2, varscan2
- TRAV3 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 503/1176 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs745851436; called by muse, mutect2, varscan2
- TRPV5 | c.1807A>T p.M603L | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV54689560; called by muse, mutect2, varscan2
- UBA1 | c.2639G>A p.R880Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as COSV60115380; called by muse, mutect2, varscan2
- UGT2B10 | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 165/447 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55323357; called by muse, mutect2, varscan2
- ULK2 | c.2269G>T p.G757W | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as rs756637387, COSV64448357; called by muse, mutect2, varscan2
- USH1C | c.647T>A p.L216Q | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50034582; called by muse, mutect2, varscan2
- USH2A | c.7452-1G>A p.X2484_splice | Splice Site (SNP) | VAF 47/146 reads (32%) | catalogued as COSV56431977; called by muse, mutect2, varscan2
- USP11 | c.1509G>T p.M503I (on ENST00000218348; = p.M460I on NM_001371072.1) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.437); catalogued as COSV54475881; called by muse, mutect2, varscan2
- VCAM1 | c.2089C>G p.P697A | Missense Mutation (SNP) | VAF 172/541 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as COSV54119671, COSV54121830; called by muse, mutect2, varscan2
- VDR | c.1196A>T p.K399M | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57470478; called by muse, mutect2, varscan2
- VSIG2 | c.316C>A p.L106M | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52519461; called by muse, mutect2, varscan2
- WDR12 | c.445G>T p.V149L | Missense Mutation (SNP) | VAF 63/237 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.119); catalogued as COSV53688666; called by muse, mutect2, varscan2
- WDR88 | c.745T>G p.S249A | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63452669; called by muse, mutect2, varscan2
- XIRP2 | c.3314A>T p.E1105V (on ENST00000628543; = p.E1280V on NM_152381.6) | Missense Mutation (SNP) | VAF 57/341 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54732735; called by muse, mutect2, varscan2
- XPR1 | c.470G>T p.R157L | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62555583, COSV62560399; called by muse, mutect2, varscan2
- ZC3HAV1L | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV51965103; called by muse, mutect2, varscan2
- ZNF202 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); catalogued as rs150835875; called by muse, mutect2, varscan2
- ZNF398 | c.1606G>C p.E536Q (on ENST00000475153 / NM_170686.3; = p.E365Q on NM_020781.4) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV60066760; called by muse, mutect2, varscan2
- ZNF561 | c.384G>T p.R128S | Missense Mutation (SNP) | VAF 140/453 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57179015; called by muse, mutect2, varscan2
- ZNF561 | c.383G>T p.R128M | Missense Mutation (SNP) | VAF 144/458 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV57179025; called by muse, mutect2, varscan2
- ZNF780A | c.1172G>A p.C391Y | Missense Mutation (SNP) | VAF 194/697 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61816683; called by muse, mutect2, varscan2
- ZNF99 | c.325A>T p.K109* | Nonsense Mutation (SNP) | VAF 79/206 reads (38%) | catalogued as COSV68056677; called by muse, mutect2, varscan2
- A4GNT | c.84del p.C29Afs*18 | Frame Shift Del (DEL) | VAF 88/244 reads (36%) | called by mutect2, pindel, varscan2
- ACOT11 | c.1748G>A p.G583E | Missense Mutation (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2
- ATP2B3 | c.2238+2del p.X746_splice | Splice Site (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- BMP6 | c.1264C>T p.Q422* | Nonsense Mutation (SNP) | VAF 14/290 reads (5%) | called by muse, mutect2
- CACNA1E | c.5486A>T p.Q1829L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2
- CIITA | c.2959_2967del p.Q987_L989del | In Frame Del (DEL) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- COL1A2 | c.4007del p.P1336Hfs*33 | Frame Shift Del (DEL) | VAF 77/271 reads (28%) | called by mutect2, pindel, varscan2
- IDE | c.1309delinsGT p.I437Vfs*24 | Frame Shift Ins (INS) | VAF 62/390 reads (16%) | called by pindel, varscan2*
- IGDCC3 | c.436del p.Q146Rfs*24 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- IGHV3-15 | c.83del p.G28Efs*4 | Frame Shift Del (DEL) | VAF 34/178 reads (19%) | called by mutect2, pindel, varscan2
- NYAP2 | c.945del p.K316Rfs*57 | Frame Shift Del (DEL) | VAF 19/140 reads (14%) | called by mutect2, pindel, varscan2
- REG1A | c.320dup p.N108Efs*26 | Frame Shift Ins (INS) | VAF 42/140 reads (30%) | called by mutect2, pindel, varscan2
- SLC8A3 | c.1603del p.E535Nfs*35 | Frame Shift Del (DEL) | VAF 20/121 reads (17%) | called by mutect2, pindel, varscan2
- XRCC1 | c.1459del p.D487Tfs*6 | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | called by mutect2, pindel, varscan2
- ZNF718 | c.1323_1334del p.K442_H445del | In Frame Del (DEL) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- AHNAK | c.14301T>A p.P4767= | Silent (SNP) | VAF 134/602 reads (22%) | catalogued as rs1305874855, COSV57229489; called by muse, mutect2, varscan2
- ATP1A4 | c.2628T>C p.F876= | Silent (SNP) | VAF 149/508 reads (29%) | catalogued as COSV63628445; called by muse, mutect2, varscan2
- ATP6V1E1 | c.570A>C p.I190= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV53660185; called by muse, mutect2, varscan2
- C7 | c.2436G>A p.E812= | Silent (SNP) | VAF 64/139 reads (46%) | catalogued as COSV57476003, COSV57480560; called by muse, mutect2, varscan2
- CC2D2A | c.1161C>T p.Y387= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV67505504; called by mutect2, varscan2
- CCN3 | c.738G>A p.V246= | Silent (SNP) | VAF 72/296 reads (24%) | catalogued as rs777234634, COSV52385285; called by muse, mutect2, varscan2
- CSRNP2 | c.57C>T p.G19= | Silent (SNP) | VAF 99/230 reads (43%) | catalogued as COSV57335354; called by muse, mutect2, varscan2
- CUL1 | c.1593A>G p.L531= | Silent (SNP) | VAF 72/237 reads (30%) | catalogued as rs764878022, COSV57392339; called by muse, mutect2, varscan2
- CYP46A1 | c.363C>T p.F121= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs780187016, COSV55894567; called by muse, mutect2
- DPP6 | c.591T>C p.D197= (on ENST00000377770 / NM_001364500.2; = p.D135= on NM_001936.5) | Silent (SNP) | VAF 46/159 reads (29%) | catalogued as COSV59607126, COSV59643496; called by muse, mutect2, varscan2
- EBF2 | c.999C>T p.F333= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV68780260; called by muse, mutect2, varscan2
- ERCC3 | c.1821A>T p.I607= | Silent (SNP) | VAF 29/201 reads (14%) | catalogued as COSV53425477, COSV53429832; called by muse, mutect2, varscan2
- FRMD5 | c.276C>T p.F92= | Silent (SNP) | VAF 163/393 reads (41%) | catalogued as COSV68725308; called by muse, mutect2, varscan2
- GABBR1 | c.1443G>A p.L481= | Silent (SNP) | VAF 12/298 reads (4%) | called by muse, mutect2
- GFI1B | c.336C>A p.A112= | Silent (SNP) | VAF 66/174 reads (38%) | catalogued as COSV59746992; called by muse, varscan2
- GIMAP8 | c.591A>T p.G197= | Silent (SNP) | VAF 143/457 reads (31%) | catalogued as COSV56233736; called by muse, mutect2, varscan2
- HFM1 | c.414T>A p.P138= | Silent (SNP) | VAF 69/230 reads (30%) | catalogued as COSV54036826; called by muse, mutect2, varscan2
- HOMEZ | c.324C>T p.L108= | Silent (SNP) | VAF 18/497 reads (4%) | catalogued as COSV62537782; called by muse, mutect2
- HSF2 | c.21G>T p.V7= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV63774567; called by muse, mutect2
- IFNA13 | c.33C>A p.A11= | Silent (SNP) | VAF 84/232 reads (36%) | catalogued as COSV71924589; called by muse, mutect2, varscan2
- LRIG2 | c.2184C>T p.N728= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV63164176; called by muse, mutect2, varscan2
- LRP1B | c.4962A>G p.L1654= | Silent (SNP) | VAF 38/287 reads (13%) | catalogued as rs756757502, COSV67272335; called by muse, mutect2, varscan2
- MAP3K19 | c.1980T>A p.P660= | Silent (SNP) | VAF 81/334 reads (24%) | catalogued as COSV59642077; called by muse, mutect2, varscan2
- OR1S2 | c.807A>G p.V269= | Silent (SNP) | VAF 23/218 reads (11%) | catalogued as COSV56920683; called by muse, mutect2, varscan2
- OR4D10 | c.756G>A p.V252= | Silent (SNP) | VAF 143/669 reads (21%) | catalogued as COSV73260202; called by muse, mutect2, varscan2
- OR4S2 | c.201G>T p.V67= | Silent (SNP) | VAF 70/551 reads (13%) | catalogued as COSV56748323; called by muse, varscan2
- OR5B12 | c.474T>A p.T158= | Silent (SNP) | VAF 57/321 reads (18%) | catalogued as COSV56904588, COSV56906654; called by muse, mutect2, varscan2
- OR5R1 | c.303G>T p.L101= | Silent (SNP) | VAF 116/230 reads (50%) | catalogued as COSV56573614; called by muse, mutect2
- OR9I1 | c.324A>T p.A108= | Silent (SNP) | VAF 146/260 reads (56%) | catalogued as COSV56927461; called by muse, mutect2, varscan2
- PCDH15 | c.1605C>T p.D535= | Silent (SNP) | VAF 75/220 reads (34%) | catalogued as rs370348265, COSV57271337; ClinVar: likely benign; called by muse, mutect2, varscan2
- PHIP | c.2196A>T p.V732= | Silent (SNP) | VAF 59/208 reads (28%) | catalogued as COSV51510497; called by muse, mutect2, varscan2
- PPRC1 | c.4452G>T p.S1484= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as COSV53384631, COSV53388449; called by muse, mutect2, varscan2
- PRRC2C | c.3957G>C p.L1319= (on ENST00000367742; = p.L1317= on NM_015172.4) | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as COSV58912724; called by muse, mutect2, varscan2
- PTK2 | c.1149C>A p.G383= | Silent (SNP) | VAF 375/1789 reads (21%) | catalogued as COSV61792197; called by muse, mutect2, varscan2
- RAD54B | c.1134A>G p.L378= | Silent (SNP) | VAF 88/281 reads (31%) | catalogued as rs759006816, COSV60254717; called by muse, mutect2, varscan2
- RGS12 | c.3312G>A p.K1104= | Silent (SNP) | VAF 2/12 reads (17%) | catalogued as COSV58755501, COSV58756853; called by muse, mutect2
- RGS7 | c.241T>C p.L81= | Silent (SNP) | VAF 42/165 reads (25%) | catalogued as COSV58553917; called by muse, mutect2, varscan2
- SCN1A | c.5352C>A p.V1784= (on ENST00000303395 / NM_001202435.3; = p.V1773= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 77/375 reads (21%) | catalogued as COSV57686503; called by muse, mutect2, varscan2
- SFTPC | c.12C>T p.G4= | Silent (SNP) | VAF 4/39 reads (10%) | called by mutect2, varscan2
- SPHKAP | c.111G>A p.P37= | Silent (SNP) | VAF 69/254 reads (27%) | catalogued as rs201911651, COSV60878469; called by muse, mutect2, varscan2
- SUSD3 | c.723G>T p.L241= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV64937521; called by muse, mutect2, varscan2
- SYNE1 | c.19998G>C p.L6666= (on ENST00000367255 / NM_182961.4; = p.L6595= on NM_033071.3) | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as COSV55095669; called by muse, mutect2, varscan2
- SYNGAP1 | c.228C>T p.S76= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs147049139; called by muse, mutect2, varscan2
- TBC1D14 | c.786A>G p.L262= | Silent (SNP) | VAF 43/92 reads (47%) | catalogued as COSV68987190; called by muse, mutect2, varscan2
- TBCC | c.831C>T p.S277= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV55131151; called by muse, mutect2, varscan2
- THBS2 | c.138C>A p.R46= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs779026599, COSV64682095; called by muse, mutect2, varscan2
- THY1 | c.165C>A p.T55= | Silent (SNP) | VAF 44/320 reads (14%) | catalogued as COSV52455253; called by muse, mutect2, varscan2
- TNN | c.837G>T p.L279= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV53435001; called by muse, mutect2, varscan2
- TRIM61 | c.465G>A p.V155= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as rs1408042618; called by mutect2, varscan2
- TTC26 | c.198T>C p.C66= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as COSV58274278; called by muse, mutect2, varscan2
- UNCX | c.339C>A p.T113= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV100310287, COSV60332931, COSV60333656; called by mutect2, varscan2
- USP30 | c.1302C>T p.Y434= | Silent (SNP) | VAF 50/175 reads (29%) | catalogued as rs773455265, COSV57451458; called by muse, mutect2, varscan2
- ZNF536 | c.1134C>T p.C378= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs755287534, COSV62820506; called by muse, mutect2, varscan2
- ZNF619 | c.1182C>T p.S394= | Silent (SNP) | VAF 118/322 reads (37%) | catalogued as COSV59031244; called by muse, mutect2, varscan2
- ZNF80 | c.717C>T p.H239= | Silent (SNP) | VAF 73/166 reads (44%) | catalogued as COSV57362483; called by muse, mutect2, varscan2
- SLC8A3 | c.1785-2956G>T | Intron (SNP) | VAF 112/734 reads (15%) | catalogued as COSV99385699, COSV99385745; called by muse, mutect2, varscan2
- TMEM234 | c.387+30C>G | Intron (SNP) | VAF 20/56 reads (36%) | catalogued as COSV100557237; called by muse, mutect2, varscan2
